Somatic mutation profile of tumor specimen ALCH-B4UQ-TTP1-A (aliquot ALCH-B4UQ-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4UQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,919 days).
Specimen ALCH-B4UQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee9a0fe7-5b4e-4b44-abdf-fb6e2041ff4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4UQ-NB1-A (Blood Derived Normal), aliquot ALCH-B4UQ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fb16b1e-4b8a-48e6-af9b-d59bbda90705

The open-access MAF lists 71 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, 3'UTR 2, 5'Flank 2, In Frame Del 1, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 453/1379 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 143/531 reads (27%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 60/560 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100947606, COSV64418902; called by muse, mutect2, varscan2
- ATP2A3 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs1390417806; called by muse, mutect2
- CHST1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100346207; called by muse, mutect2, varscan2
- DDX52 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 33/300 reads (11%) | catalogued as rs141903993; called by muse, mutect2, varscan2
- DOCK6 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs199852280; called by muse, mutect2, varscan2
- GAD2 | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 128/547 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99393172; called by muse, mutect2, varscan2
- HOXC13 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as rs751014305, COSV54498030, COSV54498579; called by muse, mutect2, varscan2
- IGHM | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 99/942 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); catalogued as rs782402963; called by muse, mutect2, varscan2
- KIF21B | c.2390A>G p.Q797R | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs1182437794; called by muse, mutect2, varscan2
- MLH3 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 82/1077 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs944842929; called by muse, mutect2
- PDZD11 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 57/499 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1351421724; called by muse, mutect2, varscan2
- PLCL2 | c.1433C>T p.P478L (on ENST00000615277 / NM_001144382.2; = p.P352L on NM_015184.5) | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs755734000; called by muse, mutect2, varscan2
- POM121 | c.1025G>A p.R342H (on ENST00000434423; = p.R77H on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/650 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs782310112, COSV57511657; called by muse, mutect2, varscan2
- PPHLN1 | c.1366A>G p.N456D | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs748047764; called by muse, mutect2, varscan2
- PRSS8 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 181/639 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs768681784, COSV54898001; called by muse, mutect2, varscan2
- SLC9B2 | c.1307C>G p.T436R | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1280437700; called by muse, mutect2, varscan2
- SWT1 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 25/601 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1267553681; called by muse, mutect2
- SYCP2 | c.1286C>G p.P429R | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV62770077; called by muse, mutect2, varscan2
- TIMM29 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs780319503; called by muse, mutect2
- TTC39A | c.1342_1344del p.S448del (on ENST00000447632 / NM_001297665.1; = p.S413del on NM_001080494.3) | In Frame Del (DEL) | VAF 102/418 reads (24%) | catalogued as rs750460455; called by pindel, varscan2
- ZNF423 | c.1141G>A p.D381N (on ENST00000563137 / NM_001379286.1; = p.D373N on NM_015069.4) | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs1355934465, COSV52183366; called by muse, mutect2
- ACTRT1 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 60/559 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALG14 | c.614del p.K205Sfs*25 | Frame Shift Del (DEL) | VAF 65/511 reads (13%) | called by mutect2, pindel, varscan2
- AMHR2 | c.1140+5G>A | Splice Region (SNP) | VAF 80/282 reads (28%) | called by muse, mutect2, varscan2
- ATXN7 | c.1196T>G p.I399S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- B3GLCT | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 129/894 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C22orf23 | c.72_75del p.Y25Pfs*10 | Frame Shift Del (DEL) | VAF 37/263 reads (14%) | called by mutect2, pindel, varscan2
- CACNA1A | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CATSPER1 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 45/364 reads (12%) | called by muse, mutect2, varscan2
- CCDC77 | c.584A>C p.D195A | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DDRGK1 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- DMD | c.4312C>A p.Q1438K | Missense Mutation (SNP) | VAF 89/789 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FPGT | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IPO9 | c.2444C>G p.T815S | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRF2BP2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 46/477 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITPR3 | c.3935A>G p.K1312R | Missense Mutation (SNP) | VAF 63/568 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LZTS2 | c.869C>G p.A290G | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.01); called by muse, mutect2
- MAGEB2 | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 86/391 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NDST3 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUP155 | c.1670C>T p.S557F (on ENST00000231498 / NM_153485.3; = p.S498F on NM_004298.4) | Missense Mutation (SNP) | VAF 119/833 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- POMT2 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 282/1382 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RECQL4 | c.84+1G>T p.X28_splice | Splice Site (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- SEMG2 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 59/668 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); called by muse, mutect2
- SETD1B | c.4591_4592del p.S1531Lfs*35 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by pindel, varscan2
- TTN | c.59709T>G p.S19903R (on ENST00000591111; = p.S12479R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBED4 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCCHC18 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 52/599 reads (9%) | called by muse, mutect2
- ZNF479 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 66/1591 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ZSCAN5C | c.638A>T p.K213M | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ACAN | c.1635C>T p.C545= | Silent (SNP) | VAF 125/294 reads (43%) | catalogued as rs752598382, COSV61356575; called by muse, mutect2, varscan2
- ADAMTS7 | c.4002G>T p.G1334= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- BRINP3 | c.2193A>G p.R731= | Silent (SNP) | VAF 95/442 reads (21%) | called by muse, mutect2, varscan2
- CCDC190 | c.711C>T p.F237= | Silent (SNP) | VAF 52/407 reads (13%) | catalogued as rs201168794, COSV100905825, COSV63362482; called by muse, mutect2, varscan2
- CLDN16 | c.627C>T p.A209= | Silent (SNP) | VAF 199/712 reads (28%) | catalogued as rs745542693, COSV99289875; called by muse, mutect2, varscan2
- DNAH9 | c.7224A>G p.T2408= | Silent (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- GCSAML | c.244C>T p.L82= | Silent (SNP) | VAF 62/646 reads (10%) | catalogued as COSV100826017; called by muse, mutect2
- IER5L | c.327C>T p.H109= | Silent (SNP) | VAF 54/238 reads (23%) | called by muse, varscan2
- ITPRID1 | c.2970C>T p.G990= | Silent (SNP) | VAF 407/1622 reads (25%) | catalogued as rs1562663842; called by muse, mutect2, varscan2
- KRTAP29-1 | c.927G>T p.V309= | Silent (SNP) | VAF 142/677 reads (21%) | called by mutect2, varscan2
- MNX1 | c.795C>T p.Y265= | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- MPL | c.1332C>A p.A444= | Silent (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.36471G>T p.L12157= | Silent (SNP) | VAF 82/571 reads (14%) | called by muse, mutect2, varscan2
- C22orf34 | n.361G>A | RNA (SNP) | VAF 29/205 reads (14%) | catalogued as rs1569028296; called by muse, mutect2, varscan2
- DLGAP5 | c.2419-188G>T | Intron (SNP) | VAF 112/583 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457874 T>A | 5'Flank (SNP) | VAF 44/612 reads (7%) | called by muse, mutect2, varscan2
- NT5C1B | c.1071+157G>A | Intron (SNP) | VAF 30/557 reads (5%) | catalogued as rs767717742; called by muse, mutect2
- NUP155 | c.*23G>A | 3'UTR (SNP) | VAF 37/329 reads (11%) | catalogued as rs186382138; called by muse, mutect2, varscan2
- PIP4P1 | c.*218C>A | 3'UTR (SNP) | VAF 46/590 reads (8%) | catalogued as rs947942085; called by muse, mutect2
- TIAM1 | chr21:31559405 del G | 5'Flank (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
